Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4CB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4CB-01A (Primary Tumor).

[page 1 of 7]
Patient Name: [REDACTED] Copath #: [REDACTED]
MRN: [REDACTED] Service: Surgical Service Collected: [REDACTED]
DOB: [REDACTED] Visit #: [REDACTED] Resulted: [REDACTED]
Gender: [REDACTED] Location: [REDACTED]
HCN: [REDACTED] Facility: [REDACTED]
Ordering MD: [REDACTED]

Surgical Pathology Consultation Report

ICD-0-3

SPECIMEN(S) RECEIVED

1. Lymph-Node: submental
2. Neck: right neck level I
3. Neck: right neck level II
4. Neck: right neck level III
5. Neck: left neck level I
6. Neck: left neck level II
7. Neck: left neck level III
8. Soft Tissue: anterior gingival tissue
9. Neck: anterior marginal mandiblectomy and floor of mouth
10. Neck: right posterior margin
11. Neck: anterior tongue
12. Neck: left posterior margin

carcinoma, squamous cell, Keratinizing,
Nos 8071/3

Site: floor of mouth, Nos C04.9

W
9/26/12

DIAGNOSIS

1. "Lymph node submental".
Adipose tissue with no pathologic changes.
No lymph nodes present.
2. Right neck level I.
Metastatic squamous cell carcinoma involving one of four lymph nodes (1/4).
- a. The involved lymph node measures 0.8 cm.
- b. Negative for extracapsular invasion.Submandibular gland with mild non-specific chronic inflammation.
3. Right neck level II.
Six lymph nodes negative for tumor (0/6).
4. Right neck level III.
One lymph node negative for tumor (0/1).
5. Left neck level I.
Six lymph nodes negative for tumor (0/6).

[page 2 of 7]
Submandibular gland negative for tumor.

Status: complete

Page: 1 of 6

Patient Name: [REDACTED]	Service: Surgical Service	Copath # [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

6. Left neck level II.
Four lymph nodes negative for tumor (0/4)

7. Left neck level III.
Five lymph nodes negative for tumor (0/5).

8. Anterior gingival tissue.
Negative for tumor.

9. Oral cavity; anterior marginal mandibulectomy and floor of mouth;
resection.

Keratinizing squamous cell carcinoma, moderately differentiated.

a. Maximum tumor dimension 2.0 cm.

b. Tumor thickness 0.9 cm.

c. Positive for perineural invasion.

d. Negative for lymphovascular invasion.

e. Margins negative for tumor. The tumor is close (0.3 cm) to the
anterior gingival mucosal margin. The remaining margins are negative for
tumor (>0.5 cm).

f. Sections of bone are pending decalcification. An addendum report
will follow.

10. Right posterior margin.
Negative for tumor.

11. Anterior tongue.
Negative for tumor.

12. Left posterior margin.
Negative for tumor.

SYNOPTIC DATA

[page 3 of 7]
Clinical History:
Specimen:
Received:
Procedure:
Specimen Integrity:
Specimen Size:

No neoadjuvant therapy
Floor of mouth, NOS
Fresh
Resection
Intact
Greatest dimension: 4.8 cm
Additional dimension: 4.5 cm

Status: complete

Page: 2 of 6

Patient Name:	[REDACTED]	Copath #:	[REDACTED]
MRN:	[REDACTED]	Service: Surgical Service	Collected: [REDACTED]
DOB:	[REDACTED]	Visit #:	[REDACTED]
Gender:	[REDACTED]	Location:	Resulted: [REDACTED]
HCN:	[REDACTED]	Facility:	
Ordering MD:	[REDACTED]		

Specimen Laterality:	Additional dimension: 2.5 cm
Tumor Site:	Not specified
Tumor Focality:	Floor of mouth, NOS
Tumor Size:	Single focus
	Greatest dimension: 2.0 cm
	Additional dimension: 2.0 cm
	Additional dimension: 0.9 cm
Tumor Thickness (pT1 and pT2 tumors):	
	Tumor thickness: 0.9 mm
	Measured from ulcerated surface
Tumor Description:	Ulcerated
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Margins:	Margins uninvolved by invasive
carcinoma	
	Distance from closest margin: 0.3 cm
margin	Margin(s): anterior gingival mucosa
is not applicable	Margin status for carcinoma in situ
Treatment Effect:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Present
Lymph Nodes, Extranodal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1: Tumor 2 cm or less in greatest

[page 4 of 7]
dimension
Regional Lymph Nodes (pN): pN1: Metastasis in a single
ipsilateral lymph node, 3 cm or less in greatest dimension
Number of regional lymph nodes
examined: 26
Number of regional lymph nodes
involved: 1
Size (greatest dimension) of the
largest positive lymph node: 1.6 cm
Distant Metastasis (pM): Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Status: complete

Page: 3 of 6

Patient Name	██	Copath #	████████████████
MRN:	████████████████	Service: Surgical Servic	Collected: ██████████
DOB:	████████████████	Visit #:	████████████████
Gender:	████████	Location:	████████████████
HCN:	████████████████	Facility:	████████████████
Ordering MD:	██		

ELECTRONICALLY VERIFIED BY

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "submental".
It consists of one piece of adipose tissue measuring 2.6 x 1 x 0.1 cm.
No lymph nodes are identified.

1A specimen in toto

2. The specimen is labeled with the patient's name and "right neck level
1". It consists of portion of fibroadipose tissue measuring 4 x 3 x
2cm. The submandibular gland is unremarkable and measures 3.5 x 2 x 2
cm. Multiple lymph nodes ranging from 0.8 to 1.4 cm are identified.
Representative sections are submitted.

2A submandibular gland

2B multiple lymph nodes

3. The specimen is labeled with the patient's name and "right neck level

[page 5 of 7]
2". It consists of a portion of fibroadipose tissue measuring 4.5 x 1.7 x 1.4 cm. Multiple lymph nodes ranging from 0.7 to 1.2 cm are identified.

3A multiple lymph nodes

4. The specimen is labeled with the patient's name and "right neck level 3". It consists of portion of fibroadipose tissue measuring 6 x 3 x 1.2 cm. One lymph node measuring 0.5 cm is identified.

4A one lymph node bisected

5. The specimen is labeled with the patient's name and "left neck level 1". It consists of portion of fibroadipose tissue measuring 4 x 3 x 1.3 cm. The submandibular gland is unremarkable and measures 3.9 x 2.4 x 1 cm. Multiple lymph nodes ranging from 0.4 to 1.6 cm are identified.

5A submandibular gland

5B multiple lymph nodes

5C 1 lymph node bisected

6. The specimen is labeled with the patient's name and "left neck level

Status: complete

Page: 4 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Surgical Service

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

2". It consists of portion of fibroadipose tissue measuring 4.5 x 2.4 x 1.6 cm. Multiple lymph nodes ranging from 0.2 to 1.2 cm are identified.

6A multiple lymph nodes

7. The specimen is labeled with the patient's name and "left neck level 3". It consists of portion of fibroadipose tissue measuring 7 x 3 x 1 cm. Multiple lymph nodes ranging from 0.2 to 0.8 cm are identified.

7A multiple lymph nodes

7B one lymph node

8. The specimen is labeled with the patient's name and as "anterior gingival tissue". It consists of a fragment of tissue measuring 0.6 x 0.3 x 0.1 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

[page 6 of 7]
9. The specimen is labeled with the patient's name and as "anterior marginal mandibulectomy and floor of mouth". It consists of a mandible with floor of mouth resection with overall dimensions of 2.5 AP x 4.5 SI x 4.8 ML cm. There is an ulcerated tumor arising in the floor of mouth. The tumor measures 2.0 AP x 0.9 SI x 2.0 ML cm. There is grossly no involvement of bone by the tumour. The tumor is located at 0.3 cm from the closest anterior gingiva margin. The distance to the remaining margins are: 0.6 cm from the posterior floor of mouth margin; 0.8 cm from the right mucosal floor of mouth margin; 1.2 cm from the left mucosal floor mouth margin; and 1.7 cm from the deep inferior margin. Representative sections are submitted.

9A frozen section posterior muscle/floor of mouth margin
9B anterior gingiva mucosal margin
9C right floor of mouth mucosal margin
9D left floor of mouth mucosal margin
9E deep inferior margin
9F posterior floor of mouth margin
9G-9H tumor
9I right mandible resection margin (decalcification)
9J left mandible resection margin (decalcification)
9K midsection mandible and tumor (decalcification)

10. The specimen is labeled with the patient's name and as "right posterior margin". It consists of a fragment of tissue measuring 3 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

Status: complete

Page: 5 of 6

Patient Name:	[REDACTED]	Copath #	[REDACTED]
MRN:	[REDACTED]	Service: Surgical Serv	Collected: [REDACTED]
DOB:	[REDACTED]	Visit #:	[REDACTED]
Gender:	[REDACTED]	Location:	[REDACTED]
HCN:	[REDACTED]	Facility:	[REDACTED]
Ordering MD:	[REDACTED]		

10A frozen section control

11. The specimen is labeled with the patient's name and as "anterior tongue". It consists of a fragment of tissue measuring 2.8 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

11A frozen section control

12. The specimen is labeled with the patient's name and as "left posterior margin". It consists of a fragment of tissue measuring 4 x 0.2 x 0.3 cm. The specimen is submitted in toto for frozen section.

[page 7 of 7]
12A frozen section control

QUICK SECTION

8. Anterior gingival tissue:
Negative for carcinoma

9. Anterior mandibulectomy:
Posterior muscle margin negative for carcinoma on macroscopic and
microscopic assessment

10. Right posterior margin:
Negative for carcinoma

11. Anterior tongue:
Negative for carcinoma

12. Left posterior margin:
Negative for carcinoma

Status: complete

Page: 6 of 6

8/23/12

Source: NCI Genomic Data Commons file b44cb472-7a0e-4e73-a703-a9fcfec7db89 (TCGA-CQ-A4CB.7D9A7AF2-48F5-4FDE-B350-B749E7BEC2F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).